Somatic mutation profile of tumor specimen TCGA-06-0646-01A (aliquot TCGA-06-0646-01A-01D-1492-08) from TCGA case TCGA-06-0646, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 61.0 years (22,273 days).
Specimen TCGA-06-0646-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c53c79a0-aba9-421b-812d-aeeed15ea445.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-06-0646-10A (Blood Derived Normal), aliquot TCGA-06-0646-10A-01D-1492-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/bc444bb7-6254-4a11-9fc0-0b4324020927

The open-access MAF lists 35 somatic variants for this specimen: 26 protein-altering or splice-affecting, 7 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 23, Silent 7, Frame Shift Del 2, Splice Region 1, RNA 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AKR1A1 | c.4G>A p.A2T | Missense Mutation (SNP) | VAF 84/178 reads (47%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as COSV61086926; called by muse, mutect2, varscan2
- CCDC17 | c.1599G>A p.Q533= | Splice Region (SNP) | VAF 5/23 reads (22%) | catalogued as COSV59647792; called by muse, mutect2, varscan2
- CDKN2C | c.43del p.R15Gfs*4 | Frame Shift Del (DEL) | VAF 36/71 reads (51%) | catalogued as COSV52954294, COSV52955354, COSV52955909; called by mutect2, pindel, varscan2
- CEP350 | c.439G>A p.E147K | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT tolerated (0.07); PolyPhen benign (0.086); catalogued as COSV62485718; called by muse, varscan2
- CHEK1 | c.696A>T p.K232N | Missense Mutation (SNP) | VAF 67/241 reads (28%) | SIFT tolerated (0.32); PolyPhen benign (0.056); catalogued as COSV54024603; called by muse, mutect2, varscan2
- COL1A2 | c.688C>T p.P230S | Missense Mutation (SNP) | VAF 58/213 reads (27%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.449); catalogued as COSV51961682; called by muse, mutect2, varscan2
- COL22A1 | c.4538G>A p.R1513Q | Missense Mutation (SNP) | VAF 52/146 reads (36%) | SIFT tolerated (0.11); PolyPhen benign (0.02); catalogued as rs200298766, COSV100278836, COSV57343458; called by muse, mutect2, varscan2
- DNAAF1 | c.332C>T p.T111M | Missense Mutation (SNP) | VAF 44/108 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.949); catalogued as rs375812500; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FCRL2 | c.1379C>A p.P460Q | Missense Mutation (SNP) | VAF 41/100 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV63834277; called by muse, mutect2, varscan2
- FUS | c.1418G>A p.R473H | Missense Mutation (SNP) | VAF 92/182 reads (51%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0); catalogued as rs777102516, COSV54218579; called by muse, mutect2, varscan2
- HCK | c.1493C>T p.P498L | Missense Mutation (SNP) | VAF 32/76 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs752568964, COSV52944879, COSV52948028; called by muse, mutect2, varscan2
- HYOU1 | c.2287del p.S763Pfs*30 | Frame Shift Del (DEL) | VAF 90/300 reads (30%) | catalogued as COSV68217308; called by mutect2, pindel, varscan2
- MAGI1 | c.3797C>T p.P1266L | Missense Mutation (SNP) | VAF 71/194 reads (37%) | SIFT tolerated (0.35); PolyPhen benign (0.001); catalogued as rs1214834973, COSV58317576; called by muse, mutect2, varscan2
- MAPK1IP1L | c.107G>T p.G36V | Missense Mutation (SNP) | VAF 42/57 reads (74%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.124); catalogued as COSV67106576; called by muse, mutect2, varscan2
- MKS1 | c.994G>A p.V332I | Missense Mutation (SNP) | VAF 92/134 reads (69%) | SIFT tolerated (0.67); PolyPhen benign (0.038); catalogued as rs775391594, COSV58305144; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MON1B | c.1417G>A p.A473T | Missense Mutation (SNP) | VAF 79/183 reads (43%) | SIFT tolerated (0.13); PolyPhen benign (0.11); catalogued as COSV50249460; called by muse, mutect2, varscan2
- MUC16 | c.1398C>G p.S466R | Missense Mutation (SNP) | VAF 106/323 reads (33%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.001); catalogued as COSV67478775; called by muse, mutect2, varscan2
- OR1D5 | c.553C>A p.L185M | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT tolerated (0.08); PolyPhen probably damaging (1); catalogued as COSV73859549, COSV73859660; called by muse, mutect2, varscan2
- PCDHB6 | c.2191C>G p.P731A | Missense Mutation (SNP) | VAF 88/324 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.043); catalogued as COSV50707526; called by muse, mutect2, varscan2
- PDPR | c.2447T>G p.F816C | Missense Mutation (SNP) | VAF 74/432 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); catalogued as COSV55353993; called by muse, mutect2, varscan2
- POU2AF1 | c.631T>C p.S211P | Missense Mutation (SNP) | VAF 57/118 reads (48%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs1210287156, COSV67577452; called by muse, mutect2, varscan2
- RELN | c.6107C>T p.A2036V | Missense Mutation (SNP) | VAF 21/78 reads (27%) | SIFT tolerated (0.25); PolyPhen benign (0.034); catalogued as rs368438329; called by muse, mutect2, varscan2
- RYR2 | c.7060G>A p.A2354T | Missense Mutation (SNP) | VAF 17/51 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.033); catalogued as rs773070579, COSV63697822; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SEMA3C | c.730T>C p.F244L | Missense Mutation (SNP) | VAF 30/120 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.069); catalogued as COSV54850943; called by muse, mutect2, varscan2
- SORCS2 | c.2342G>A p.R781Q | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT tolerated (0.09); PolyPhen benign (0.149); catalogued as rs760356538, COSV61176570; called by muse, mutect2, varscan2
- USP6 | c.1192C>T p.R398W | Missense Mutation (SNP) | VAF 11/91 reads (12%) | SIFT tolerated, low confidence (0.13); PolyPhen possibly damaging (0.689); catalogued as rs577155682, COSV100003695, COSV51485533; called by muse, mutect2, varscan2
- DSC3 | c.1965G>A p.R655= | Silent (SNP) | VAF 61/178 reads (34%) | catalogued as rs781050028, COSV64573977; called by muse, mutect2, varscan2
- LCK | c.81A>T p.I27= | Silent (SNP) | VAF 45/119 reads (38%) | catalogued as rs1296543827, COSV60741517; called by muse, mutect2, varscan2
- LLGL2 | c.513G>C p.S171= | Silent (SNP) | VAF 22/125 reads (18%) | catalogued as rs553929286, COSV51349058, COSV51418044; called by muse, mutect2, varscan2
- PAOX | c.1386C>T p.G462= | Silent (SNP) | VAF 16/27 reads (59%) | catalogued as rs769136556, COSV53373255; called by muse, mutect2, varscan2
- TRRAP | c.5859G>A p.E1953= (on ENST00000359863 / NM_001244580.1; = p.E1935= on NM_003496.3) | Silent (SNP) | VAF 31/130 reads (24%) | catalogued as COSV62848990; called by muse, mutect2, varscan2
- USP38 | c.3039A>T p.G1013= | Silent (SNP) | VAF 58/146 reads (40%) | catalogued as COSV61026695; called by muse, mutect2, varscan2
- ZNF174 | c.1149G>A p.Q383= | Silent (SNP) | VAF 48/97 reads (49%) | catalogued as COSV51903329; called by muse, mutect2, varscan2
- ETNK1 | c.-202C>G | 5'UTR (SNP) | VAF 16/37 reads (43%) | catalogued as COSV56887294; called by muse, mutect2, varscan2
- ZNF322P1 | n.1134G>A | RNA (SNP) | VAF 164/466 reads (35%) | called by muse, mutect2, varscan2
